Somatic mutation profile of tumor specimen TARGET-10-PASJMK-09A (aliquot TARGET-10-PASJMK-09A-01D) from TARGET case TARGET-10-PASJMK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.3 years (2,300 days).
Specimen TARGET-10-PASJMK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e41a01cd-8101-4813-97b8-95d2299ce177.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASJMK-10A (Blood Derived Normal), aliquot TARGET-10-PASJMK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c0a0312-ca92-4604-9257-37e5ef2b73c6

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Frame Shift Ins 1, In Frame Ins 1, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GALT | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs750433449, COSV50744890; called by muse, mutect2, varscan2
- ARMH1 | c.1199A>T p.N400I | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV62637663; called by muse, mutect2, varscan2
- BAZ1A | c.3244A>G p.M1082V | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV62410932; called by muse, mutect2, varscan2
- BRINP3 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs142073525, COSV100818504; called by muse, mutect2, varscan2
- C2orf78 | c.714G>T p.R238S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.442); catalogued as COSV68518322; called by muse, mutect2, varscan2
- EFR3B | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427362459, COSV53121608; called by muse, mutect2, varscan2
- HUWE1 | c.5021A>G p.N1674S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV53353318; called by muse, mutect2, varscan2
- PAF1 | c.767A>G p.Q256R | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55395069; called by muse, mutect2, varscan2
- PCDHGA1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs140226913, COSV65296451; called by muse, mutect2, varscan2
- PTPRR | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.109); catalogued as rs775822570, COSV104392843, COSV51728386; called by muse, mutect2, varscan2
- TRIM65 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs531815348, COSV53933795; called by muse, mutect2, varscan2
- TSPYL2 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 121/305 reads (40%) | catalogued as COSV64921282; called by muse, mutect2, varscan2
- DNM2 | c.1530_1531del p.R510Sfs*46 (on ENST00000355667 / NM_001005360.3; = p.R510Sfs*42 on NM_004945.3) | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by pindel, varscan2
- IGHD6-19 | c.20delinsGGTCCTTGGGCACCCCTTT p.Y7delinsWSLGTPF | In Frame Ins (INS) | VAF 19/52 reads (37%) | called by pindel, varscan2*
- KMT2D | c.9121_9124dup p.L3042Pfs*8 | Frame Shift Ins (INS) | VAF 22/106 reads (21%) | called by mutect2, pindel, varscan2
- COL7A1 | c.1911G>A p.P637= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as rs1211687404; called by muse, mutect2, varscan2
- FAM47A | c.984G>A p.E328= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as rs766985853; called by muse, mutect2, varscan2
- PLEC | c.7428G>A p.A2476= (on ENST00000322810 / NM_201380.4; = p.A2366= on NM_000445.5) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs574508108; called by muse, mutect2, varscan2
- PTPRG | c.1704G>A p.S568= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs746918640, COSV55629894; called by muse, mutect2, varscan2
- SLC6A2 | c.390C>A p.I130= | Silent (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- IGHV3-20 | chr14:106210935 ins GGGTTTGGTAGTA | 3'Flank (INS) | VAF 14/74 reads (19%) | called by mutect2, pindel
